Somatic mutation profile of tumor specimen TCGA-13-0751-01A (aliquot TCGA-13-0751-01A-01D-0446-08) from TCGA case TCGA-13-0751, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 44.6 years (16,304 days).
Specimen TCGA-13-0751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 438ec6d6-1c8d-4729-a028-2dd7a2550a40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0751-10A (Blood Derived Normal), aliquot TCGA-13-0751-10A-01D-0446-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5314d4a8-9e13-48e7-82db-25961bfae2af

The open-access MAF lists 56 somatic variants for this specimen: 37 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Nonsense Mutation 4, RNA 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD2 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61773700; called by muse, varscan2
- AGPAT4 | c.321C>G p.S107R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV57245171; called by muse, mutect2
- AHNAK | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV57211261; called by muse, mutect2, varscan2
- AIM2 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV63699372; called by muse, mutect2, varscan2
- AK6 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs759423974, COSV51457387; called by muse, mutect2, varscan2
- ANKRD6 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60230772; called by muse, mutect2, varscan2
- ANXA13 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 29/867 reads (3%) | catalogued as COSV99146126; called by muse, mutect2
- C11orf52 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 28/120 reads (23%) | catalogued as COSV53714543; called by muse, mutect2, varscan2
- CELF1 | c.761G>T p.G254V (on ENST00000358597 / NM_001376422.1; = p.G250V on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as COSV60111482; called by muse, mutect2, varscan2
- CFAP69 | c.2599A>C p.K867Q | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV60185403; called by muse, varscan2
- CHRAC1 | c.357C>G p.D119E | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99636183; called by muse, mutect2
- CLMN | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461371267, COSV100112950, COSV54179033; called by muse, mutect2
- DUSP1 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53319950; called by muse, mutect2, varscan2
- FAM133B | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs957467424, COSV70075524; called by muse, mutect2, varscan2
- GABRB3 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 195/437 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs373823173; called by muse, mutect2, varscan2
- GARRE1 | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55098454, COSV55098562; called by muse, mutect2, varscan2
- GMNN | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100017724; called by muse, mutect2
- GPR149 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 192/999 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs747890765, COSV67666925; called by muse, mutect2, varscan2
- GPR75 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as rs771403683, COSV100766092; called by muse, mutect2
- GYG2 | c.613A>T p.R205W | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58549797; called by muse, mutect2, varscan2
- HDGFL3 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100220740; called by muse, mutect2, varscan2
- IGSF8 | c.479dup p.G161Rfs*18 | Frame Shift Ins (INS) | VAF 14/95 reads (15%) | catalogued as rs754902711; called by mutect2, varscan2
- KNDC1 | c.3953G>T p.R1318L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100464796; called by muse, mutect2, varscan2
- LNX2 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV60337576; called by muse, mutect2
- PDE7B | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV57495915, COSV57502388; called by muse, mutect2, varscan2
- PDPK1 | c.1402G>C p.G468R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51912763, COSV99239226; called by muse, mutect2, varscan2
- PLCD4 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV68743478; called by muse, mutect2, varscan2
- RING1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs752665608, COSV63002481; called by muse, mutect2, varscan2
- SPEN | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101005235; called by muse, mutect2
- SRCAP | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs903401621, COSV52667822, COSV52677074; called by muse, mutect2
- SRP68 | c.754G>T p.G252W | Missense Mutation (SNP) | VAF 26/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100326099; called by muse, mutect2
- TEFM | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 11/132 reads (8%) | catalogued as COSV58973746; called by muse, mutect2
- VRTN | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56440418; called by muse, mutect2, varscan2
- ZNF486 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV58718650; called by muse, mutect2, varscan2
- ASTN2 | c.3368_3377del p.S1123Mfs*12 (on ENST00000313400 / NM_001365069.1; = p.S1072Mfs*12 on NM_014010.5) | Frame Shift Del (DEL) | VAF 55/161 reads (34%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 636/1153 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TP53 | c.1042_1043insAAGGCCT p.L348* | Nonsense Mutation (INS) | VAF 71/86 reads (83%) | called by mutect2, pindel, varscan2
- AGAP6 | c.1185C>T p.G395= (on ENST00000374056 / NM_001365867.1; = p.G418= on NM_001077665.2) | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV100929065; called by muse, varscan2
- CHRNA1 | c.486G>A p.T162= (on ENST00000261007 / NM_001039523.3; = p.T137= on NM_000079.4) | Silent (SNP) | VAF 45/200 reads (23%) | catalogued as rs758613275, COSV53682630; called by muse, mutect2, varscan2
- CNTNAP5 | c.1191A>C p.T397= | Silent (SNP) | VAF 125/296 reads (42%) | catalogued as COSV70482651; called by muse, mutect2, varscan2
- CPO | c.31T>C p.L11= | Silent (SNP) | VAF 114/216 reads (53%) | catalogued as rs1221844139, COSV55939467; called by muse, mutect2, varscan2
- CST1 | c.165T>C p.Y55= | Silent (SNP) | VAF 73/250 reads (29%) | catalogued as rs3188296, COSV59055217; called by muse, mutect2, varscan2
- EMG1 | c.291T>C p.D97= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99781094; called by muse, mutect2
- HEPACAM2 | c.1239A>G p.E413= (on ENST00000394468 / NM_001039372.4; = p.E401= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/335 reads (30%) | catalogued as COSV59059779; called by muse, mutect2, varscan2
- HYAL2 | c.255G>C p.L85= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV51700443; called by muse, mutect2, varscan2
- IGKV6D-41 | c.63T>C p.D21= | Silent (SNP) | VAF 53/233 reads (23%) | called by muse, mutect2, varscan2
- P3H1 | c.339T>A p.L113= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV52533055; called by muse, mutect2, varscan2
- RGL4 | c.963T>C p.A321= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs369635839; called by mutect2, varscan2
- SAMD4A | c.1851T>C p.S617= | Silent (SNP) | VAF 77/187 reads (41%) | catalogued as COSV99200671; called by muse, mutect2, varscan2
- SLCO2A1 | c.1548C>T p.L516= | Silent (SNP) | VAF 11/274 reads (4%) | catalogued as COSV100188978; called by muse, mutect2
- SPEN | c.8547G>A p.Q2849= | Silent (SNP) | VAF 42/246 reads (17%) | catalogued as COSV65360794; called by muse, mutect2, varscan2
- TBC1D4 | c.3189T>C p.H1063= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as rs1263599427, COSV66488833; called by muse, mutect2, varscan2
- UFL1 | c.1239T>C p.S413= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV65149483; called by muse, mutect2, varscan2
- HLA-L | n.684A>T | RNA (SNP) | VAF 24/375 reads (6%) | called by muse, mutect2
- PAX3 | c.586+416C>A | Intron (SNP) | VAF 25/148 reads (17%) | catalogued as COSV51338255; called by muse, varscan2
- SNORD115-42 | n.68A>G | RNA (SNP) | VAF 70/149 reads (47%) | called by muse, mutect2, varscan2
